Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3994, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3994-01A (Primary Tumor).

Diagnosis:

Right hemicolectomy preparation with an ulcerated colon carcinoma characterized histologically as a moderately differentiated, partially mucinous, colorectal adenocarcinoma, located 11.5 cm aborally to Bauhin's valve, and encircling the colon wall at a length of 3.5 cm. Invasive spread of the tumor within all intestinal wall layers up to the bordering mesocolic fatty tissue.

Oral and aboral resection margin and greater omentum are tumor-free.

Appendix with clear post-inflammatory fibrosis of the wall.

Therefore the tumor stage is pT3, pN1 (2/24) L0 V0; G2 R0

Source: NCI Genomic Data Commons file 4b85d8ca-8133-49f7-8dde-0099b62a8b26 (TCGA-AA-3994.55C50C9D-4520-4BD3-8ABF-31FE50EC5537.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).